Somatic mutation profile of tumor specimen TCGA-EL-A3ZO-01A (aliquot TCGA-EL-A3ZO-01A-11D-A23M-08) from TCGA case TCGA-EL-A3ZO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 79.2 years (28,924 days).
Specimen TCGA-EL-A3ZO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a000cfbd-7a96-4b4c-8f8f-06cb22bc53bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZO-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZO-11A-12D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c643a48-973f-4bda-b52c-7c02dd2b6847

The open-access MAF lists 90 somatic variants for this specimen: 64 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 25, Nonsense Mutation 9, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DMD | c.7402G>T p.E2468* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as rs128626253, CM084899, CX921033, COSV100625712; ClinVar: pathogenic; called by muse, mutect2
- LHFPL5 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104893976, CM062818, COSV100798916; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs374984401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATAD2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.425); catalogued as rs750619146, COSV99783959; called by muse, mutect2, varscan2
- ATAD5 | c.3698C>G p.P1233R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV100429597; called by muse, mutect2, varscan2
- BRD7 | c.1613-1G>A p.X538_splice | Splice Site (SNP) | VAF 13/100 reads (13%) | catalogued as rs540625147, COSV99575620; called by muse, mutect2, varscan2
- C3orf62 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV99648929; called by muse, mutect2, varscan2
- CATSPERG | c.2446C>A p.L816M | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV99285980; called by muse, mutect2, varscan2
- CDC7 | c.1301G>C p.R434T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99319509; called by muse, mutect2, varscan2
- CHD1 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV99399017; called by muse, mutect2, varscan2
- CLASP2 | c.2168C>A p.S723* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100222366; called by muse, mutect2, varscan2
- CNOT1 | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as rs1375743379, COSV100408385; called by muse, mutect2, varscan2
- CREBZF | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV99476091, COSV99476099; called by muse, mutect2, varscan2
- CRISPLD2 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs1452577420, COSV99295299; called by muse, mutect2
- FHL2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100362779; called by muse, mutect2, varscan2
- FRYL | c.7687G>A p.E2563K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as COSV99975488; called by muse, mutect2, varscan2
- GGCT | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV99139123; called by muse, mutect2, varscan2
- GRIN2A | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV58054484; called by muse, mutect2, varscan2
- HLA-DPB1 | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756011172, COSV101330957; called by muse, mutect2, varscan2
- HPDL | c.589C>G p.P197A | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.503); catalogued as rs1174177632, COSV100587882; called by muse, mutect2
- HSPA13 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV99579829; called by muse, mutect2, varscan2
- IPO9 | c.2853G>C p.W951C | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.552); catalogued as COSV100843302; called by muse, mutect2
- ITGA10 | c.2488C>G p.L830V | Missense Mutation (SNP) | VAF 47/550 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100994653; called by muse, mutect2
- KCNS2 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99750651; called by muse, mutect2, varscan2
- KDM2B | c.943G>C p.A315P | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100997105; called by muse, mutect2
- LGSN | c.1426C>G p.L476V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101040200; called by muse, mutect2, varscan2
- LY75 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715868; called by muse, mutect2, varscan2
- LYST | c.9304G>C p.D3102H | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101087910; called by muse, mutect2
- MYH10 | c.5557G>T p.E1853* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as COSV99343922; called by muse, mutect2, varscan2
- NDUFA7 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV100035389; called by muse, mutect2
- NFAT5 | c.3358C>T p.Q1120* | Nonsense Mutation (SNP) | VAF 8/190 reads (4%) | catalogued as COSV100590375, COSV63029729; called by muse, mutect2
- PARP10 | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV100477605; called by muse, mutect2, varscan2
- PCDHGA2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.187); catalogued as COSV53945663, COSV53950220; called by muse, mutect2, varscan2
- PIK3R1 | c.2071C>G p.L691V (on ENST00000521381 / NM_181523.3; = p.L421V on NM_181504.4) | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99140502; called by muse, mutect2, varscan2
- POLQ | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as COSV99951483; called by muse, mutect2, varscan2
- PTPRZ1 | c.5767C>T p.R1923C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs142748552; called by muse, mutect2, varscan2
- PTPRZ1 | c.6628G>C p.E2210Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV101099339; called by muse, mutect2, varscan2
- REV1 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV99300448; called by muse, mutect2
- RNF113A | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV101006948; called by muse, mutect2
- RYR1 | c.6244G>A p.E2082K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as COSV100614231; called by muse, mutect2, varscan2
- SCAPER | c.2274G>A p.M758I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV100236963; called by muse, mutect2, varscan2
- SEC62 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100427857, COSV100427914; called by muse, mutect2, varscan2
- SLC17A7 | c.1058T>C p.I353T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV99676665; called by muse, mutect2, varscan2
- SLC50A1 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV100310178, COSV100310460; called by muse, mutect2
- SLX4 | c.3637G>C p.V1213L | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99567514; called by muse, mutect2, varscan2
- SLX4 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as rs145194745; called by muse, mutect2, varscan2
- SPG11 | c.6253C>T p.Q2085* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as rs751464582, COSV99967913; called by muse, mutect2
- SPTA1 | c.6025C>T p.R2009C | Missense Mutation (SNP) | VAF 187/735 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs374336960, COSV63754955; called by muse, mutect2, varscan2
- SPTBN4 | c.7631C>G p.S2544C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99398807; called by muse, mutect2
- SRC | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV62441269; called by muse, varscan2
- SRP68 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV100325904; called by muse, mutect2, varscan2
- TCF7L1 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as rs1486052719, COSV99964119; called by muse, mutect2
- TET1 | c.3403C>T p.H1135Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV101017515; called by muse, mutect2, varscan2
- TMEM171 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99824827; called by muse, mutect2, varscan2
- TMEM192 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as rs556977126, COSV100121986; called by muse, mutect2, varscan2
- TRPS1 | c.1717A>T p.S573C (on ENST00000220888 / NM_001330599.2; = p.S586C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV99627994; called by muse, mutect2
- USP26 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100896505; called by muse, mutect2, varscan2
- VWA2 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.224); catalogued as COSV100073250; called by muse, mutect2, varscan2
- WASL | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56136325; called by muse, mutect2, varscan2
- WDR6 | c.1861A>G p.I621V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100556112; called by muse, mutect2, varscan2
- FANCB | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MVP | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 8/247 reads (3%) | called by muse, mutect2
- ZBTB32 | c.1377G>A p.W459* | Nonsense Mutation (SNP) | VAF 7/200 reads (4%) | called by muse, mutect2
- APPL2 | c.927C>T p.L309= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs955847740, COSV51592336; called by muse, mutect2
- ARHGEF17 | c.1482C>T p.S494= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs753477594, COSV99734787; called by muse, mutect2, varscan2
- C7 | c.828C>T p.F276= | Silent (SNP) | VAF 5/103 reads (5%) | catalogued as COSV100495299, COSV57474043; called by muse, mutect2
- CAMK2B | c.192C>A p.I64= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV51667706, COSV99322673; called by muse, mutect2, varscan2
- CEACAM8 | c.81C>T p.F27= | Silent (SNP) | VAF 25/198 reads (13%) | catalogued as rs146608676, COSV99747386; called by muse, mutect2, varscan2
- CLMN | c.741A>G p.L247= | Silent (SNP) | VAF 85/232 reads (37%) | catalogued as rs761209466, COSV100111940; called by muse, mutect2, varscan2
- DPF1 | c.174C>T p.C58= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100831403; called by muse, mutect2, varscan2
- FER1L6 | c.1800G>A p.L600= | Silent (SNP) | VAF 53/223 reads (24%) | catalogued as COSV101205349; called by muse, varscan2
- H1-2 | c.417G>A p.K139= | Silent (SNP) | VAF 27/217 reads (12%) | catalogued as rs547786942, COSV100642215, COSV59190207, COSV59191946; called by muse, mutect2, varscan2
- KCNH4 | c.1578C>T p.I526= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs1303724921, COSV52915277; called by muse, mutect2, varscan2
- KRT25 | c.729C>T p.A243= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV56446720; called by muse, mutect2, varscan2
- LTN1 | c.1338C>G p.L446= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV63733134; called by muse, mutect2
- NPY4R | c.657C>G p.L219= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100966101; called by mutect2, varscan2
- PCDHB5 | c.1584C>T p.F528= | Silent (SNP) | VAF 52/231 reads (23%) | catalogued as COSV50651148; called by muse, mutect2, varscan2
- PDIK1L | c.444G>C p.L148= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV100957650; called by muse, mutect2, varscan2
- PSG9 | c.157C>T p.L53= | Silent (SNP) | VAF 78/279 reads (28%) | catalogued as rs144736946; called by muse, mutect2, varscan2
- PSMD7 | c.384G>A p.P128= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs541071308, COSV99542532, COSV99542858; called by muse, varscan2
- PTPN3 | c.889T>C p.L297= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs771119485, COSV99355335; called by muse, mutect2, varscan2
- RP1L1 | c.5244G>C p.G1748= | Silent (SNP) | VAF 41/299 reads (14%) | catalogued as COSV101222893; called by muse, mutect2, varscan2
- SMG8 | c.1515C>T p.P505= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99958636; called by muse, mutect2, varscan2
- TENT5B | c.606C>G p.L202= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV100006437; called by muse, mutect2, varscan2
- TG | c.2412G>A p.V804= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99598660; called by muse, mutect2, varscan2
- THOC6 | c.423C>T p.L141= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs951582788, COSV99560371; called by muse, mutect2, varscan2
- VSTM4 | c.567C>A p.I189= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100251191, COSV100251226; called by muse, mutect2
- ZKSCAN4 | c.1488C>T p.F496= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV101043340; called by muse, mutect2, varscan2
- CEP295 | chr11:93730526 C>G | 3'Flank (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
